Somatic mutation profile of tumor specimen TCGA-DD-A4NA-01A (aliquot TCGA-DD-A4NA-01A-11D-A25V-10) from TCGA case TCGA-DD-A4NA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.4 years (24,603 days).
Specimen TCGA-DD-A4NA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef90c7c2-0eff-46bd-b8b2-1a4d9a173df2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NA-11A (Solid Tissue Normal), aliquot TCGA-DD-A4NA-11A-11D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0c9e5b5-2c60-41d9-90e1-9aeb053a2506

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 79/175 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.4886C>T p.A1629V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as rs368905104; called by muse, mutect2, varscan2
- BAP1 | c.586T>G p.W196G | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56229887; called by muse, mutect2, varscan2
- C16orf96 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs367941862; called by muse, mutect2, varscan2
- CEP164 | c.2434G>T p.G812W | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54037796; called by muse, mutect2, varscan2
- EML4 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as rs760391629, COSV59292100; called by muse, mutect2, varscan2
- HLA-E | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV64927168; called by muse, mutect2, varscan2
- IRAK4 | c.1043T>C p.I348T | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV71210223; called by muse, mutect2, varscan2
- LHB | c.343C>G p.R115G | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV55484053; called by muse, mutect2, varscan2
- LRRD1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV58467208; called by muse, mutect2
- MAPK7 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV55189109; called by muse, mutect2, varscan2
- MUC16 | c.36323G>A p.G12108D | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.069); catalogued as COSV67441313; called by muse, mutect2, varscan2
- PDE7B | c.34del p.I12Sfs*21 | Frame Shift Del (DEL) | VAF 48/89 reads (54%) | catalogued as COSV57492625; called by mutect2, pindel, varscan2
- PODNL1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as rs147712582; called by muse, mutect2, varscan2
- RPP40 | c.624A>C p.K208N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as COSV60291179; called by muse, mutect2, varscan2
- RXYLT1 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs756576089, COSV54167420; called by muse, mutect2, varscan2
- SAMD8 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV101014127, COSV65508963; called by muse, mutect2, varscan2
- SDCBP2 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV60588182; called by muse, mutect2, varscan2
- SDK2 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV66180583; called by muse, mutect2, varscan2
- SGSM1 | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV101240881, COSV68508529; called by muse, varscan2
- SUCO | c.3128A>T p.Y1043F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs916177336, COSV55261479; called by muse, mutect2, varscan2
- TAS2R39 | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71470787; called by muse, mutect2, varscan2
- THBS3 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 56/139 reads (40%) | catalogued as rs552940002, COSV57425625; called by muse, mutect2, varscan2
- TRPM2 | c.1359C>G p.D453E | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55965213, COSV55975757; called by muse, mutect2, varscan2
- THBS3 | c.1470del p.Q491Rfs*114 | Frame Shift Del (DEL) | VAF 92/313 reads (29%) | called by mutect2, pindel, varscan2
- DMGDH | c.2142C>T p.A714= | Silent (SNP) | VAF 94/260 reads (36%) | catalogued as rs1272448763, COSV54860091; called by muse, mutect2, varscan2
- GEMIN8 | c.711C>T p.V237= | Silent (SNP) | VAF 77/220 reads (35%) | catalogued as COSV60549958; called by muse, mutect2, varscan2
- HCCS | c.708G>A p.K236= | Silent (SNP) | VAF 65/192 reads (34%) | catalogued as COSV58238729, COSV58239425; called by muse, mutect2, varscan2
- IVL | c.1371G>C p.V457= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV64215322; called by muse, mutect2, varscan2
- LRP2 | c.11070C>T p.Y3690= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as COSV55539061; called by muse, mutect2, varscan2
- MEX3A | c.24A>G p.G8= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as COSV64140958; called by muse, mutect2, varscan2
- RASSF4 | c.702A>G p.K234= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58484259; called by muse, mutect2, varscan2
- SLC6A2 | c.867T>C p.N289= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV54912715; called by muse, mutect2, varscan2
- TRPC7 | c.660C>T p.N220= | Silent (SNP) | VAF 97/223 reads (43%) | catalogued as COSV61452104; called by muse, mutect2, varscan2
- USP38 | c.1866T>C p.P622= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV61024682; called by muse, mutect2, varscan2
- EP400P1 | n.625C>T | RNA (SNP) | VAF 18/55 reads (33%) | catalogued as rs367613174; called by muse, mutect2, varscan2
